Somatic mutation profile of tumor specimen TCGA-CR-7388-01A (aliquot TCGA-CR-7388-01A-11D-2012-08) from TCGA case TCGA-CR-7388, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 70.4 years (25,728 days).
Specimen TCGA-CR-7388-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5cd1f65-8d1b-4d6d-ab81-21a83314f032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7388-10A (Blood Derived Normal), aliquot TCGA-CR-7388-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e0a6a18-b1e4-4e40-8daf-00d2b3a3fb36

The open-access MAF lists 728 somatic variants for this specimen: 542 protein-altering or splice-affecting, 168 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 470, Silent 168, Nonsense Mutation 40, Frame Shift Del 14, Splice Site 13, Intron 7, RNA 6, 3'UTR 2, Splice Region 2, 3'Flank 2, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL3 | c.3349C>T p.R1117* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs868044680, COSV52463509; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- GLI2 | c.2013del p.S673Afs*5 (on ENST00000361492 / NM_001374353.1; = p.S690Afs*5 on NM_005270.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as rs876661325; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NIPBL | c.3855+2T>C p.X1285_splice | Splice Site (SNP) | VAF 15/116 reads (13%) | catalogued as rs886043046, COSV99243060; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTCH1 | c.114del p.L39Cfs*41 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs751977093; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.582); catalogued as COSV100879516; called by muse, mutect2, varscan2
- ABAT | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs139121258, COSV99191052; called by muse, mutect2, varscan2
- ABCC12 | c.2005G>C p.D669H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100253379; called by muse, mutect2
- ABCC9 | c.3851G>T p.S1284I | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV99687544; called by muse, varscan2
- ACAN | c.7147G>A p.E2383K (on ENST00000560601 / NM_001369268.1; = p.E2307K on NM_001135.3) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs985414009, COSV100719462; called by muse, mutect2
- ACKR4 | c.926C>G p.S309C | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99392754; called by muse, mutect2
- ACO1 | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs888997704, COSV100008748; called by muse, mutect2, varscan2
- ACP1 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99681866; called by muse, mutect2
- ACSL4 | c.1034C>T p.P345L (on ENST00000340800 / NM_022977.2; = p.P304L on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1200189941, COSV100538244; called by muse, mutect2
- ADAMTS16 | c.2101G>T p.G701W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56982349, COSV99943348; called by muse, mutect2, varscan2
- ADAMTS19 | c.3209C>T p.T1070I | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99183658; called by muse, mutect2
- ADAMTS20 | c.1214T>C p.L405P | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101240558; called by muse, mutect2, varscan2
- ADGRB3 | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99487124; called by muse, mutect2
- ADGRV1 | c.12573G>C p.W4191C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101316651; called by muse, mutect2, varscan2
- ADPRH | c.844G>T p.V282F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV100813375; called by muse, mutect2, varscan2
- AGK | c.516C>A p.V172= | Splice Region (SNP) | VAF 18/185 reads (10%) | catalogued as COSV100814740; called by muse, mutect2
- AHNAK | c.8587G>A p.D2863N | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as COSV99949998; called by muse, mutect2
- AL136295.1 | c.1971G>C p.K657N | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.511); catalogued as COSV99938355; called by muse, mutect2, varscan2
- ALDH1L1 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56413477, COSV99857613; called by muse, mutect2, varscan2
- ALDH2 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99923326; called by muse, mutect2, varscan2
- ALDOB | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100878941; called by muse, mutect2, varscan2
- ALMS1 | c.10882C>G p.R3628G | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM050171, COSV100043993; called by muse, mutect2, varscan2
- ALPK2 | c.5278A>T p.K1760* | Nonsense Mutation (SNP) | VAF 17/139 reads (12%) | catalogued as COSV100864901; called by muse, mutect2, varscan2
- ALPL | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100876983; called by muse, mutect2, varscan2
- AMBRA1 | c.1375C>T p.Q459* (on ENST00000458649 / NM_001367468.1; = p.Q369* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100095557, COSV54056487; called by muse, mutect2, varscan2
- AMER1 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 16/134 reads (12%) | catalogued as CM109965, COSV100367152, COSV57662286; called by muse, mutect2, varscan2
- AMER3 | c.1108G>C p.G370R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100366982; called by muse, mutect2, varscan2
- AMTN | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100219875, COSV59489663; called by muse, mutect2, varscan2
- ANKRD12 | c.5355del p.R1787Gfs*12 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as COSV100040736; called by mutect2, pindel, varscan2
- ANKRD17 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); catalogued as COSV100430078; called by muse, mutect2
- ANKRD50 | c.892A>G p.K298E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101539063, COSV72385403; called by muse, mutect2, varscan2
- ANXA7 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.428); catalogued as COSV65824400; called by mutect2, varscan2
- AP1G2 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs757149895, COSV100436619; called by muse, mutect2, varscan2
- AP1S2 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100236954; called by muse, mutect2, varscan2
- APH1A | c.379A>T p.I127F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as COSV52528085, COSV99354561; called by muse, varscan2
- APOB | c.8638C>T p.Q2880* | Nonsense Mutation (SNP) | VAF 18/199 reads (9%) | catalogued as rs760198312, COSV99268554; called by muse, mutect2
- ARHGAP11A | c.2077A>T p.T693S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV100277011; called by muse, mutect2, varscan2
- ARHGAP12 | c.1940G>C p.G647A | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100260971; called by muse, mutect2
- ARHGAP6 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100273642; called by muse, mutect2
- ARHGEF37 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100382389; called by muse, mutect2, varscan2
- ARID1A | c.2765del p.G922Afs*2 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | catalogued as rs1557611083; called by mutect2, pindel, varscan2
- ARMCX5 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as rs1323042694, COSV99863582; called by muse, mutect2
- ASB4 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.119); catalogued as COSV100367340; called by muse, mutect2, varscan2
- ASXL3 | c.6230G>T p.S2077I | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99326937; called by muse, mutect2, varscan2
- ATN1 | c.2532G>C p.E844D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.625); catalogued as COSV100755983; called by muse, mutect2
- ATP10A | c.2494G>C p.E832Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.223); catalogued as COSV100791616; called by muse, mutect2, varscan2
- ATP1B1 | c.361A>G p.M121V | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV100891642; called by muse, mutect2
- ATP2C1 | c.53T>A p.I18N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.239); catalogued as COSV100147041; called by muse, mutect2, varscan2
- ATP7A | c.2551G>T p.V851F | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100431849; called by muse, mutect2
- ATP8A2 | c.2752G>T p.V918L | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99684755; called by muse, mutect2, varscan2
- ATR | c.5050C>G p.H1684D | Missense Mutation (SNP) | VAF 18/277 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100638665; called by muse, mutect2
- ATRNL1 | c.212C>A p.S71* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100747097; called by muse, mutect2, varscan2
- ATRX | c.5885C>T p.S1962F | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV100971572; called by muse, mutect2
- ATRX | c.2114A>G p.D705G | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.612); catalogued as rs781804632, COSV100971574; ClinVar: benign; called by muse, mutect2, varscan2
- ATXN7L1 | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV100597028; called by muse, varscan2
- AVPR1A | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100146797; called by muse, mutect2, varscan2
- BEND2 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV101192272; called by muse, mutect2, varscan2
- BEST3 | c.1133G>A p.W378* | Nonsense Mutation (SNP) | VAF 33/128 reads (26%) | catalogued as COSV100438100; called by muse, mutect2, varscan2
- BIRC6 | c.10280C>A p.S3427Y | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101429129; called by muse, mutect2
- BIRC6 | c.12896C>T p.S4299F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101429132, COSV101429230; called by muse, mutect2, varscan2
- BMP4 | c.746G>C p.G249A | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.284); catalogued as COSV99817181; called by muse, mutect2, varscan2
- BRAF | c.2062G>C p.E688Q (on ENST00000288602 / NM_001374244.1; = p.E648Q on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99971055; called by muse, mutect2, varscan2
- BRINP1 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV99777143; called by muse, mutect2, varscan2
- BRINP3 | c.1925A>T p.E642V | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV100819581; called by muse, mutect2, varscan2
- BTNL9 | c.656C>G p.A219G | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100576298, COSV59797541; called by muse, mutect2, varscan2
- C12orf42 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100173004; called by muse, mutect2, varscan2
- C1orf141 | c.1112C>G p.S371* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as rs1260880595, COSV100924406; called by muse, mutect2, varscan2
- C2CD6 | c.1342A>C p.I448L | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99634874; called by muse, mutect2, varscan2
- C2orf68 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV100108350; called by muse, mutect2, varscan2
- C3AR1 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as rs374256772, COSV99369073; called by muse, mutect2, varscan2
- C5orf51 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.455); catalogued as rs1271905635, COSV101068901, COSV67565463; called by mutect2, varscan2
- C8A | c.1554G>T p.Q518H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as COSV63486937, COSV63487021; called by muse, mutect2, varscan2
- C9 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54675037; called by muse, mutect2, varscan2
- CACNA1C | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs533892755, COSV59698705; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASKIN2 | c.2809G>C p.E937Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.446); catalogued as COSV100051039; called by muse, varscan2
- CATSPER1 | c.684G>T p.R228S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100376292; called by muse, varscan2
- CCDC120 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as COSV100900533, COSV100900731; called by muse, mutect2, varscan2
- CCDC6 | c.454-2A>T p.X152_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99569916; called by muse, mutect2, varscan2
- CCDC6 | c.86C>G p.S29W | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV99569919; called by muse, mutect2
- CCHCR1 | c.1798G>C p.A600P | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99459345; called by muse, mutect2, varscan2
- CCT8L2 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100743196; called by muse, mutect2, varscan2
- CD200R1 | c.446T>G p.V149G (on ENST00000471858 / NM_170780.3; = p.V172G on NM_138806.4) | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99867918; called by muse, mutect2
- CDH19 | c.1963G>C p.D655H | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1463795508, COSV100052496; called by muse, mutect2, varscan2
- CDH8 | c.1187A>G p.Y396C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100184448; called by muse, mutect2, varscan2
- CDK9 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV100953722; called by muse, mutect2, varscan2
- CEMIP | c.2961C>G p.I987M | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV99587416; called by muse, mutect2, varscan2
- CEMIP2 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100987533; called by muse, mutect2, varscan2
- CFAP44 | c.2492G>T p.R831L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99870438; called by muse, mutect2, varscan2
- CFAP52 | c.1246C>G p.H416D | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100235650; called by muse, mutect2, varscan2
- CHML | c.752C>G p.S251* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100087947; called by muse, mutect2, varscan2
- CHRM2 | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as COSV100280818, COSV100282088; called by muse, mutect2
- CHSY3 | c.1870C>G p.L624V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.124); catalogued as rs368982175; called by muse, mutect2, varscan2
- CILP | c.593A>T p.Q198L | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV99974039; called by muse, mutect2, varscan2
- CIT | c.5696A>T p.K1899M | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99951217; called by muse, mutect2, varscan2
- CLRN2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.055); catalogued as COSV101492699, COSV71825233; called by muse, mutect2, varscan2
- CMYA5 | c.5688G>T p.L1896F | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV101484242; called by muse, mutect2, varscan2
- CNKSR3 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1330310276, COSV101527243, COSV72161946; called by muse, mutect2, varscan2
- CNTN1 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100751985, COSV61646301; called by muse, mutect2, varscan2
- CNTRL | c.5851C>T p.Q1951* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99444114; called by muse, mutect2
- COL14A1 | c.3857A>G p.Y1286C | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99920934; called by muse, mutect2, varscan2
- COL1A2 | c.2518C>A p.P840T | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99801351; called by muse, mutect2, varscan2
- COL4A5 | c.3035del p.G1012Vfs*9 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | catalogued as COSV60360155; called by mutect2, varscan2
- CPEB4 | c.1490C>G p.P497R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV54175131, COSV99437798; called by muse, mutect2
- CRB3 | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); catalogued as COSV100375463; called by muse, mutect2, varscan2
- CSF2RA | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs190144821, COSV62625688; called by muse, mutect2, varscan2
- CSMD3 | c.10756G>A p.D3586N (on ENST00000297405 / NM_001363185.1; = p.D3417N on NM_052900.3) | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99850199; called by muse, mutect2
- CSTF2T | c.1225G>T p.G409C | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100484336; called by muse, mutect2, varscan2
- CTAGE6 | c.1070A>T p.K357I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101417897; called by muse, varscan2
- CTNND2 | c.3044G>A p.S1015N | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100481580; called by muse, mutect2
- CTNND2 | c.1234G>C p.A412P | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100481581; called by muse, mutect2, varscan2
- CTNS | c.740T>C p.F247S | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV99251627; called by muse, mutect2, varscan2
- CUX1 | c.2022C>G p.I674M | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99473387; called by muse, mutect2
- CXCL13 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.066); catalogued as COSV99724361; called by muse, mutect2, varscan2
- CYP2F1 | c.1288T>G p.S430A | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV100463070; called by muse, mutect2, varscan2
- DBT | c.733C>G p.P245A | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100923647; called by muse, mutect2, varscan2
- DCAF12L2 | c.896T>A p.L299Q | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV100758904; called by muse, mutect2, varscan2
- DCDC1 | c.2440C>A p.Q814K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as COSV60838549; called by muse, mutect2, varscan2
- DCLK2 | c.91T>C p.S31P | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV99652849; called by muse, mutect2, varscan2
- DDX46 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100844937, COSV62798513; called by muse, mutect2, varscan2
- DENND2B | c.2600C>T p.S867L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100567934; called by muse, mutect2, varscan2
- DEUP1 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as rs374648091, COSV53209665; called by muse, mutect2, varscan2
- DHFR | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV101459096; called by muse, mutect2, varscan2
- DIDO1 | c.5483C>T p.P1828L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV99827366; called by muse, mutect2, varscan2
- DKC1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101059901; called by muse, mutect2
- DLGAP1 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV100234366, COSV59795407; called by muse, mutect2, varscan2
- DLGAP1 | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.331); catalogued as rs745392034, COSV100227779, COSV100234369; called by muse, mutect2, varscan2
- DMD | c.7370C>A p.S2457Y | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV100629702; called by muse, mutect2, varscan2
- DMXL1 | c.2170G>C p.E724Q | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770957208, COSV100225172; called by muse, mutect2, varscan2
- DNAH1 | c.6185C>T p.S2062L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV101327265; called by mutect2, varscan2
- DNM2 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.351); catalogued as COSV100118172; called by muse, mutect2
- DOCK1 | c.3689G>C p.C1230S | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as COSV99733296; called by muse, mutect2, varscan2
- DPP4 | c.638C>G p.A213G | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as COSV100859142; called by muse, mutect2, varscan2
- DUSP5 | c.749A>T p.D250V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100851947; called by muse, mutect2, varscan2
- DYNC1H1 | c.10651G>C p.E3551Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100795518; called by muse, mutect2
- EEA1 | c.4040G>C p.R1347T | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100468646, COSV59288730; called by muse, mutect2
- EIF2B2 | c.749G>C p.G250A | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99837795; called by muse, mutect2, varscan2
- ENOX2 | c.1778C>A p.A593D (on ENST00000338144 / NM_001382520.1; = p.A564D on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100584650; called by muse, mutect2
- EPB41L2 | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100441495; called by muse, mutect2, varscan2
- EPB41L3 | c.2722G>T p.E908* | Nonsense Mutation (SNP) | VAF 24/160 reads (15%) | catalogued as COSV100550541; called by muse, mutect2, varscan2
- EPS8L2 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs774067035, COSV100585781; called by muse, mutect2, varscan2
- ERICH3 | c.4571C>T p.S1524F | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as rs745496149, COSV58617827; called by muse, mutect2, varscan2
- ERICH3 | c.4015G>C p.A1339P | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as COSV100446031; called by muse, mutect2, varscan2
- ESRP1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100619723; called by muse, mutect2, varscan2
- ESRRG | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100754038; called by muse, mutect2, varscan2
- EXOSC9 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99697191; called by muse, mutect2
- EXT1 | c.1027G>T p.G343W | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs978347552, CM058249, CM099161; called by muse, mutect2
- EYA1 | c.1543T>C p.Y515H | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100380421; called by muse, mutect2, varscan2
- FABP2 | c.397T>A p.*133Rext*34 | Nonstop Mutation (SNP) | VAF 17/102 reads (17%) | catalogued as COSV99916875, COSV99917025; called by muse, mutect2, varscan2
- FAM122C | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV100888307; called by muse, mutect2, varscan2
- FAM135B | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99358370; called by muse, mutect2, varscan2
- FAM217B | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs936173181, COSV100674698, COSV62565162; called by muse, mutect2, varscan2
- FAM47A | c.1220G>C p.G407A | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.187); catalogued as COSV100650109; called by muse, mutect2, varscan2
- FAM47B | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs1031464198, COSV100264696; called by muse, mutect2, varscan2
- FANCM | c.275G>C p.R92P | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99361229; called by muse, mutect2, varscan2
- FAT3 | c.4564G>T p.E1522* | Nonsense Mutation (SNP) | VAF 57/210 reads (27%) | catalogued as COSV53094893, COSV99971876; called by muse, mutect2, varscan2
- FAT4 | c.4864C>G p.Q1622E | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.31); catalogued as COSV101272917; called by muse, mutect2, varscan2
- FBN2 | c.4858A>T p.T1620S | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99331197; called by muse, mutect2, varscan2
- FCRL4 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 41/140 reads (29%) | catalogued as COSV99620220; called by muse, mutect2, varscan2
- FCRL4 | c.863G>C p.G288A | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as rs1447453792, COSV99620563; called by muse, mutect2, varscan2
- FGD1 | c.2620G>C p.E874Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.29); catalogued as COSV100911274; called by muse, mutect2
- FHOD3 | c.1388G>T p.R463L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99941396, COSV99943362; called by muse, mutect2, varscan2
- FLG | c.3080C>G p.S1027* | Nonsense Mutation (SNP) | VAF 213/683 reads (31%) | catalogued as COSV100912352; called by muse, mutect2, varscan2
- FMN2 | c.364A>G p.S122G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs781073421, COSV100147548; called by muse, mutect2, varscan2
- FMO4 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 34/474 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV63001997; called by muse, mutect2
- FNDC3B | c.1124A>T p.H375L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100395134; called by muse, mutect2, varscan2
- FOXK1 | c.1051-2A>G p.X351_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100196012; called by muse, mutect2, varscan2
- FRAS1 | c.10949A>T p.Q3650L | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV99356331; called by muse, mutect2, varscan2
- FRMD7 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.591); catalogued as rs770097894, COSV100048557; called by muse, mutect2
- GALK2 | c.961C>G p.Q321E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100509303; called by muse, mutect2, varscan2
- GAS2L3 | c.908G>T p.S303I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV57156528, COSV99903218; called by muse, mutect2, varscan2
- GATAD1 | c.690C>G p.F230L | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV99843775; called by muse, mutect2
- GBA | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as CM065220, COSV100516515; called by muse, mutect2, varscan2
- GCLM | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100934029; called by muse, mutect2
- GCM1 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs879100265, COSV99452704; called by muse, mutect2
- GDF5 | c.660G>C p.Q220H | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV100977026; called by muse, mutect2
- GEN1 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100438261; called by muse, mutect2, varscan2
- GFM1 | c.1700T>A p.L567* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99963236; called by muse, mutect2, varscan2
- GK | c.1342C>A p.L448M (on ENST00000427190 / NM_001205019.2; = p.L442M on NM_000167.6) | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100970388; called by muse, mutect2, varscan2
- GKAP1 | c.300C>G p.N100K | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100897766; called by muse, mutect2, varscan2
- GOLIM4 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV58329762; called by muse, mutect2, varscan2
- GP2 | c.1216A>C p.T406P (on ENST00000381362 / NM_001007240.3; = p.T403P on NM_001502.4) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100221686; called by muse, mutect2, varscan2
- GPRASP1 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.239); catalogued as COSV100851097; called by muse, mutect2, varscan2
- GPRIN1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV99992260; called by muse, mutect2
- GRIK5 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs137900269, COSV99491455; called by muse, mutect2, varscan2
- GRM6 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs772521795, COSV99180022; called by muse, mutect2, varscan2
- GSPT2 | c.1654G>T p.V552F | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100468429; called by muse, mutect2, varscan2
- GTF2H4 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99462357; called by mutect2, varscan2
- GTF3C1 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55187575, COSV99852168; called by muse, mutect2, varscan2
- H2AP | c.303T>A p.D101E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV100586954; called by muse, mutect2, varscan2
- HERC4 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99517625; called by muse, mutect2, varscan2
- HFM1 | c.2813G>T p.G938V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646979; called by muse, mutect2, varscan2
- HMCN1 | c.4461G>T p.W1487C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99637030; called by muse, mutect2
- HMCN1 | c.10390G>T p.A3464S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.209); catalogued as COSV99637033; called by muse, mutect2
- HMGCL | c.561+2T>G p.X187_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99354131; called by muse, mutect2, varscan2
- HNRNPM | c.674G>A p.S225N | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100335425; called by muse, varscan2
- HOXC11 | c.511T>G p.C171G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as COSV54533934, COSV99678570; called by muse, mutect2
- HSD11B2 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs375919297; called by muse, mutect2, varscan2
- HSP90B1 | c.1346A>T p.E449V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100236801; called by muse, mutect2, varscan2
- HSPA5 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as rs1167147446, COSV99413673; called by muse, mutect2, varscan2
- HSPA8 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV99914667; called by muse, mutect2
- HTR1A | c.796G>C p.G266R | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV100109312, COSV60502365; called by muse, mutect2
- ICE1 | c.3506G>A p.R1169K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as COSV99665927; called by muse, mutect2, varscan2
- IFT172 | c.4644G>C p.Q1548H | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs746827700, COSV99563545; called by muse, mutect2
- IGFLR1 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as rs754349821, COSV99495479; called by muse, mutect2, varscan2
- IGSF1 | c.1136T>A p.L379H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100812425; called by muse, mutect2, varscan2
- IGSF1 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100812269, COSV63841437; called by muse, mutect2, varscan2
- IKBIP | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV100689912; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1715C>G p.S572C | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV100782144, COSV100782148; called by muse, mutect2, varscan2
- INHBC | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as COSV100548063; called by muse, mutect2, varscan2
- INPP4A | c.2020C>T p.R674C (on ENST00000074304 / NM_001134224.1; = p.R635C on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369371577; called by mutect2, varscan2
- INTS6L | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100878346; called by muse, mutect2
- INTS7 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.161); catalogued as rs1366048767, COSV100877589; called by muse, mutect2, varscan2
- ITCH | c.2032G>C p.E678Q (on ENST00000262650 / NM_001257137.3; = p.E637Q on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99392763, COSV99393276; called by muse, mutect2, varscan2
- ITGA8 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100959850; called by muse, mutect2, varscan2
- ITGAM | c.1366T>C p.Y456H | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99793270; called by muse, mutect2, varscan2
- ITIH4 | c.2294A>G p.Q765R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.802); catalogued as COSV99819987; called by muse, mutect2, varscan2
- ITIH6 | c.1471T>A p.W491R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99514116; called by muse, mutect2, varscan2
- ITPR1 | c.7184A>G p.H2395R (on ENST00000354582; = p.H2340R on NM_002222.7) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100233514; called by muse, mutect2, varscan2
- ITPR3 | c.5000G>C p.R1667P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV100968196, COSV65407219; called by muse, mutect2, varscan2
- JPH2 | c.2057G>A p.G686D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100881802, COSV100881806; called by muse, mutect2, varscan2
- KAT8 | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99571869; called by muse, mutect2, varscan2
- KCNA5 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99364266; called by muse, mutect2, varscan2
- KCNB2 | c.1706C>G p.A569G | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV101579031; called by muse, mutect2
- KCNC1 | c.1159A>T p.I387F | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99789813; called by muse, mutect2, varscan2
- KCNH4 | c.2567C>T p.S856F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV99238009; called by muse, mutect2, varscan2
- KCNH5 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV100528421; called by muse, mutect2, varscan2
- KCNJ13 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0.204); catalogued as rs779781039, COSV99289416; called by muse, mutect2, varscan2
- KCTD8 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100759676, COSV63585096; called by muse, mutect2, varscan2
- KIDINS220 | c.4877G>C p.R1626P | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV56750217, COSV99876587; called by muse, mutect2, varscan2
- KIF13A | c.5227G>A p.E1743K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99438585; called by muse, mutect2, varscan2
- KIF13A | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs778818169, COSV52449810, COSV99434415; called by muse, mutect2, varscan2
- KIF27 | c.3962A>G p.N1321S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99927344; called by muse, mutect2, varscan2
- KLHL1 | c.1145G>T p.W382L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100918273; called by muse, mutect2, varscan2
- KLHL34 | c.703C>A p.R235S | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.189); catalogued as COSV101070012, COSV65278767; called by muse, mutect2, varscan2
- KRR1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV99875935; called by muse, mutect2, varscan2
- KRT4 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99543254; called by muse, mutect2
- KRTAP13-4 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100481861; called by muse, mutect2, varscan2
- LAMA2 | c.1683G>T p.L561F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV70356928; called by mutect2, varscan2
- LCOR | c.1571A>T p.H524L | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV99617248; called by muse, mutect2, varscan2
- LCP2 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV99253644; called by muse, mutect2, varscan2
- LEFTY1 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99686668; called by muse, mutect2, varscan2
- LILRB2 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as COSV100079723; called by muse, mutect2, varscan2
- LMNB2 | c.800A>G p.H267R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV57591140; called by muse, mutect2, varscan2
- LPAR4 | c.333C>A p.C111* | Nonsense Mutation (SNP) | VAF 35/155 reads (23%) | catalogued as COSV101425179; called by muse, mutect2, varscan2
- LPL | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV60930653; called by muse, mutect2, varscan2
- LRCH4 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100053240; called by muse, mutect2, varscan2
- LRG1 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV100015211; called by muse, mutect2, varscan2
- LRIT1 | c.1832G>C p.G611A | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100928172; called by muse, mutect2, varscan2
- LRRC56 | c.327G>T p.R109S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99530999; called by muse, mutect2, varscan2
- LRRIQ3 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV100598983, COSV63047582; called by muse, mutect2, varscan2
- LRRK2 | c.3737G>C p.R1246T | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100111324, COSV54156210; called by muse, mutect2
- LRRTM4 | c.900G>T p.W300C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297754; called by mutect2, varscan2
- LTBP1 | c.2308C>T p.H770Y (on ENST00000404816 / NM_206943.4; = p.H444Y on NM_000627.4) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.317); catalogued as COSV100618027; called by muse, varscan2
- LY6K | c.216G>C p.V72= | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99456617; called by muse, mutect2
- MAD1L1 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV56241401, COSV99767864; called by muse, mutect2, varscan2
- MAGEB1 | c.973C>A p.R325S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100975132, COSV66776023; called by muse, mutect2, varscan2
- MAGEB3 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100854701; called by muse, mutect2, varscan2
- MAGEB6 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100983887, COSV100983892; called by muse, mutect2, varscan2
- MAGEC1 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); catalogued as COSV99596732; called by muse, varscan2
- MAGEC3 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as COSV100026228; called by muse, mutect2, varscan2
- MAGI2 | c.2209C>G p.P737A | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.237); catalogued as COSV100836848; called by muse, mutect2, varscan2
- MAPK8 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.527); catalogued as COSV100827575; called by muse, mutect2
- MAS1 | c.661T>G p.S221A | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99397041; called by muse, mutect2, varscan2
- MCF2L2 | c.2323C>G p.P775A | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.191); catalogued as COSV100194159; called by muse, mutect2
- MCOLN1 | c.1335C>G p.I445M | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV51174623, COSV99654621; called by muse, mutect2, varscan2
- MCTP2 | c.1271A>T p.D424V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100537800; called by muse, mutect2, varscan2
- MDC1 | c.3523G>T p.D1175Y | Missense Mutation (SNP) | VAF 94/321 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV100903124, COSV64525169; called by muse, mutect2, varscan2
- MED12L | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs774424420, COSV56370763; called by muse, mutect2, varscan2
- MED7 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs768145478, COSV99644342; called by muse, mutect2, varscan2
- MEOX2 | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1330570273, COSV100012602; called by muse, mutect2
- MGAM | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV72075019; called by muse, mutect2
- MGAT2 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100023657; called by muse, mutect2, varscan2
- MIA | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755216468, COSV99648322; called by muse, mutect2, varscan2
- MID2 | c.946G>C p.A316P | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV99465781; called by muse, mutect2
- MMRN1 | c.2369T>G p.V790G | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV99307882; called by muse, mutect2
- MOS | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs753117912, COSV100323047; called by muse, varscan2
- MPPED1 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV100501356; called by muse, mutect2
- MRM2 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99642867; called by muse, mutect2, varscan2
- MROH9 | c.1047G>A p.W349* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100883105; called by muse, mutect2
- MSTN | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV99640865; called by muse, mutect2, varscan2
- MTERF3 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1191600219, COSV54631948, COSV99750186; called by muse, mutect2
- MTOR | c.4571G>T p.G1524V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV100816753; called by muse, mutect2, varscan2
- MUC16 | c.19183A>T p.T6395S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.029); catalogued as COSV101201999, COSV67481694; called by muse, mutect2, varscan2
- MUC17 | c.10382C>G p.S3461* | Nonsense Mutation (SNP) | VAF 166/613 reads (27%) | catalogued as COSV100075402, COSV60281438; called by muse, mutect2, varscan2
- MUC7 | c.1112T>C p.I371T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.205); catalogued as COSV100512407; called by muse, mutect2, varscan2
- MYH15 | c.3915G>C p.E1305D | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV99844475; called by muse, varscan2
- MYO1B | c.2748G>C p.R916S (on ENST00000304164; = p.R858S on NM_012223.5) | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100270249; called by muse, mutect2, varscan2
- MYO7B | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV101268410; called by muse, mutect2, varscan2
- MYOCD | c.2671G>C p.E891Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100591534; called by muse, mutect2, varscan2
- NALCN | c.949T>C p.F317L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99218250; called by muse, mutect2, varscan2
- NEDD4L | c.2077C>G p.L693V (on ENST00000400345 / NM_001144967.3; = p.L673V on NM_015277.6) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99896824; called by muse, mutect2, varscan2
- NHS | c.4090G>T p.A1364S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV101197053; called by muse, mutect2, varscan2
- NLGN1 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100850327, COSV64339768; called by muse, mutect2, varscan2
- NLGN1 | c.2102A>C p.K701T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100850328; called by muse, mutect2, varscan2
- NLRP11 | c.2561T>C p.I854T | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV100789824; called by muse, mutect2, varscan2
- NLRP12 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs753099958, COSV60745068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP3 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.131); catalogued as COSV100275338, COSV60232039; called by muse, mutect2, varscan2
- NLRP9 | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV100243577; called by muse, mutect2, varscan2
- NMI | c.82-1G>A p.X28_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99693550; called by muse, mutect2, varscan2
- NMNAT2 | c.652-1G>C p.X218_splice | Splice Site (SNP) | VAF 21/57 reads (37%) | catalogued as COSV99680469; called by muse, mutect2, varscan2
- NPAP1 | c.2647C>A p.P883T | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as rs1257981616, COSV100276326; called by muse, mutect2, varscan2
- NPFFR2 | c.141C>G p.S47R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100441408; called by muse, mutect2, varscan2
- NPR2 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100709781; called by muse, mutect2, varscan2
- NRAS | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54746950, COSV99796207; called by muse, mutect2, varscan2
- NSUN2 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV99243488; called by muse, mutect2, varscan2
- NSUN6 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101046040; called by muse, mutect2, varscan2
- NUDCD1 | c.861G>C p.L287F | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV99517816; called by muse, mutect2
- NUF2 | c.1066C>A p.Q356K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV54842038; called by muse, mutect2, varscan2
- NUP214 | c.4275C>G p.I1425M | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV100845408; called by muse, mutect2, varscan2
- OGG1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV99845002; called by muse, mutect2
- OGT | c.1258C>G p.R420G | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101035662; called by muse, mutect2
- OPN4 | c.260del p.G87Afs*3 | Frame Shift Del (DEL) | VAF 18/111 reads (16%) | catalogued as rs755184830, COSV99618698; called by mutect2, pindel, varscan2
- OR10AG1 | c.277T>A p.C93S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100400237; called by muse, mutect2, varscan2
- OR10Q1 | c.308C>A p.A103D | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV100372419; called by muse, mutect2, varscan2
- OR11H1 | c.250A>T p.K84* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99422060; called by mutect2, varscan2
- OR2B6 | c.396C>A p.Y132* | Nonsense Mutation (SNP) | VAF 14/191 reads (7%) | catalogued as COSV99773862; called by muse, mutect2
- OR2G6 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as COSV100598350; called by muse, mutect2, varscan2
- OR2H1 | c.677T>A p.I226N | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs774446503, COSV101009946; called by muse, mutect2, varscan2
- OR2T3 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 97/324 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100613257; called by muse, mutect2, varscan2
- OR4S2 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs200328594, COSV100412850, COSV56748744; called by muse, mutect2, varscan2
- OR5A2 | c.213C>A p.D71E | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100119864; called by muse, mutect2, varscan2
- OR5D13 | c.377T>G p.V126G | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100687103; called by muse, mutect2, varscan2
- OR5H1 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100641791; called by muse, varscan2
- OR5H1 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV100641792, COSV63402777; called by muse, varscan2
- OR5T2 | c.533G>T p.R178I | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100507113; called by muse, mutect2, varscan2
- OR5T3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV100282965; called by muse, mutect2, varscan2
- OR6N2 | c.874C>A p.L292I | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100210542; called by muse, mutect2, varscan2
- OR6N2 | c.464G>T p.C155F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.883); catalogued as COSV100210543; called by muse, mutect2, varscan2
- OR7D2 | c.689C>G p.S230* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100713102; called by mutect2, varscan2
- OR8A1 | c.550A>T p.M184L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1170896109, COSV99420906; called by muse, mutect2, varscan2
- OR8H2 | c.715T>A p.S239T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100542510; called by muse, mutect2, varscan2
- OXR1 | c.835G>A p.D279N (on ENST00000442977 / NM_001198532.1; = p.D278N on NM_018002.3) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV100367813; called by muse, mutect2, varscan2
- OXR1 | c.2597A>G p.Q866R (on ENST00000442977 / NM_001198532.1; = p.Q838R on NM_018002.3) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as COSV99861301; called by muse, mutect2, varscan2
- P2RY10 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as COSV50680929, COSV99409454; called by muse, mutect2
- P3H3 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99301778; called by muse, mutect2
- PABPC3 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV99880187; called by muse, mutect2, varscan2
- PAF1 | c.785T>A p.L262Q | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99656092; called by muse, mutect2, varscan2
- PAGE5 | c.142-2A>C p.X48_splice | Splice Site (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99215879; called by muse, mutect2, varscan2
- PAPPA2 | c.2077C>G p.R693G | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV100867241, COSV62789413; called by muse, mutect2, varscan2
- PARP14 | c.4545C>G p.I1515M | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV101506368; called by muse, mutect2
- PARS2 | c.46A>T p.T16S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); catalogued as COSV100988346; called by mutect2, varscan2
- PASK | c.3092A>G p.K1031R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.193); catalogued as rs1353400192, COSV99300414; called by muse, mutect2, varscan2
- PAX7 | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs1331383105, COSV64748637; called by muse, mutect2, varscan2
- PCARE | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100527943, COSV59056194; called by muse, mutect2, varscan2
- PCDH11X | c.2910C>A p.N970K | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100015861, COSV53498624; called by muse, mutect2, varscan2
- PCDH9 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs778185688, COSV60533168, COSV60569030; called by muse, mutect2, varscan2
- PCDHB12 | c.1636C>A p.L546M | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as COSV53396459; called by muse, mutect2, varscan2
- PCDHB14 | c.1893C>A p.S631R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.427); catalogued as COSV99506252; called by muse, mutect2, varscan2
- PCDHB5 | c.1502C>G p.S501C | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1438588601, COSV50650291, COSV99039329; called by muse, mutect2, varscan2
- PCDHB6 | c.1641G>C p.L547F | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1277888564, COSV99172631; called by muse, mutect2, varscan2
- PCDHGA7 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99548603; called by muse, mutect2
- PCDHGB3 | c.2232C>A p.S744R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs1385028650, COSV53924891, COSV99548598; called by muse, mutect2, varscan2
- PCDHGB7 | c.624C>G p.H208Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV53910987, COSV99548604; called by muse, mutect2, varscan2
- PDGFRA | c.680C>A p.S227* | Nonsense Mutation (SNP) | VAF 28/134 reads (21%) | catalogued as COSV99957900; called by muse, mutect2, varscan2
- PDS5B | c.1585G>T p.V529L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100221624; called by muse, mutect2, varscan2
- PEX14 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs535743906, COSV100750358; called by mutect2, varscan2
- PGLYRP2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs747502920, COSV52997435, COSV99484337; called by muse, mutect2, varscan2
- PHF3 | c.819G>C p.L273F | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as COSV100014119, COSV50315183; called by muse, mutect2
- PKHD1L1 | c.1961C>G p.S654* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV101006947; called by muse, mutect2, varscan2
- PLCB4 | c.2503T>G p.L835V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99597153; called by muse, mutect2, varscan2
- PLG | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as rs768527258, COSV99805210; called by muse, mutect2, varscan2
- PMFBP1 | c.2578G>T p.E860* (on ENST00000537465; = p.E855* on NM_031293.3) | Nonsense Mutation (SNP) | VAF 19/163 reads (12%) | catalogued as COSV52827643; called by muse, mutect2, varscan2
- PNLIPRP3 | c.152A>T p.K51M | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs867666211, COSV100982644, COSV65047421; called by muse, mutect2, varscan2
- POGLUT2 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101050832; called by muse, mutect2, varscan2
- POLA1 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV100985836; called by muse, mutect2
- POM121L12 | c.621G>T p.R207S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV101374837, COSV101374999; called by muse, mutect2, varscan2
- POSTN | c.2348-1G>A p.X783_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | catalogued as COSV101123529; called by muse, mutect2, varscan2
- POU6F1 | c.1693A>T p.K565* | Nonsense Mutation (SNP) | VAF 26/152 reads (17%) | catalogued as COSV100374928; called by muse, mutect2, varscan2
- PPEF1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV62996723; called by muse, mutect2
- PPFIA2 | c.1192C>A p.Q398K | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV61025021; called by muse, mutect2, varscan2
- PPFIBP1 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV99945576; called by muse, mutect2, varscan2
- PPP1R36 | c.534-1G>C p.X178_splice | Splice Site (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100073078; called by muse, mutect2, varscan2
- PPP2R5E | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV100518868; called by muse, mutect2
- PRRX2 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as rs144448846; called by muse, mutect2, varscan2
- PSME4 | c.2254C>G p.P752A | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); catalogued as rs1433612542, COSV101122719; called by muse, mutect2
- PTH2R | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99782988; called by muse, mutect2, varscan2
- PTPRB | c.3580T>A p.W1194R | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99719294; called by muse, mutect2, varscan2
- PTPRD | c.1507C>A p.L503I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.964); catalogued as COSV100647479, COSV61928493; called by muse, mutect2, varscan2
- PTPRM | c.842C>A p.P281Q | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100161078; called by muse, mutect2, varscan2
- PTPRU | c.4307C>T p.A1436V | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV100113892; called by muse, mutect2, varscan2
- PUM1 | c.3080A>T p.E1027V | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV99929056; called by muse, mutect2, varscan2
- PYGL | c.2335G>T p.E779* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV99369170; called by muse, mutect2, varscan2
- PYGL | c.538G>C p.A180P | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99369174; called by muse, mutect2, varscan2
- R3HDM1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV51525990; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2299C>G p.Q767E | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); catalogued as COSV100741513, COSV62783292; called by muse, mutect2, varscan2
- RAB40AL | c.578A>G p.Q193R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99505322; called by muse, mutect2, varscan2
- RAD50 | c.3502G>A p.D1168N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.677); catalogued as COSV99529802; called by muse, mutect2, varscan2
- RASGRF2 | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV104370488, COSV54141321; called by muse, mutect2, varscan2
- RASGRP3 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.074); catalogued as COSV101274916; called by mutect2, varscan2
- RASGRP4 | c.1462C>G p.Q488E | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV99385177; called by muse, mutect2, varscan2
- RBM19 | c.2823G>C p.E941D | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV99926246; called by muse, mutect2
- RC3H1 | c.1480C>G p.P494A | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99281654, COSV99281861; called by muse, mutect2, varscan2
- RELN | c.8689G>C p.D2897H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV100635070; called by muse, mutect2
- RGS1 | c.460C>G p.R154G | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV100817595, COSV66506739; called by muse, mutect2, varscan2
- RIC1 | c.1603-2A>T p.X535_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV52605019, COSV99318144; called by muse, mutect2
- RIMBP2 | c.2275G>T p.E759* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99900768; called by muse, varscan2
- RIPOR2 | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs202204524; called by muse, mutect2
- RIPOR2 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99430273; called by muse, mutect2, varscan2
- RLIM | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV100223354; called by muse, mutect2
- RNASEH2A | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV99677436; called by mutect2, varscan2
- RPL6 | c.300G>C p.K100N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV99176197; called by muse, mutect2, varscan2
- RRN3 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV99549173; called by muse, mutect2, varscan2
- RUFY2 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs777887240, COSV100700167; called by muse, mutect2, varscan2
- RUVBL2 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.19); catalogued as COSV99669303; called by muse, mutect2, varscan2
- SATB2 | c.1906G>T p.V636L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99612912; called by muse, mutect2, varscan2
- SAXO1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV101000212; called by muse, mutect2, varscan2
- SCN8A | c.5334C>G p.D1778E | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100634360; called by muse, mutect2, varscan2
- SCN9A | c.747G>T p.M249I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as COSV100314463, COSV57602133; called by muse, mutect2, varscan2
- SCRN1 | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV54130963; called by muse, mutect2, varscan2
- SEC16A | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 11/109 reads (10%) | catalogued as COSV99260380; called by muse, mutect2, varscan2
- SEM1 | c.198G>C p.K66N | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV99949663; called by muse, mutect2
- SF3B3 | c.1003G>T p.V335F | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV100210309; called by muse, mutect2, varscan2
- SH2D1A | c.250A>T p.I84F | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758372; called by muse, mutect2, varscan2
- SH3KBP1 | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101115285; called by muse, mutect2, varscan2
- SHROOM4 | c.2548C>A p.L850I | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.193); catalogued as COSV99174875; called by muse, mutect2, varscan2
- SIGLEC12 | c.1743G>T p.Q581H (on ENST00000291707 / NM_053003.4; = p.Q463H on NM_033329.2) | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV52463748, COSV99389649; called by muse, mutect2, varscan2
- SIPA1L3 | c.4531G>A p.E1511K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.966); catalogued as rs768560161, COSV55917048; called by muse, mutect2, varscan2
- SLC15A4 | c.1536C>G p.I512M | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV99903845; called by muse, mutect2, varscan2
- SLC16A7 | c.1024T>A p.L342I | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV99676936; called by muse, mutect2
- SLC25A31 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs267600020, COSV55418138; called by mutect2, varscan2
- SLC30A7 | c.75G>T p.W25C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV63018201; called by muse, mutect2, varscan2
- SLFN12 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as COSV100513255; called by muse, mutect2, varscan2
- SLITRK5 | c.1915C>A p.P639T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61523945; called by muse, mutect2, varscan2
- SLITRK6 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV101233306; called by muse, mutect2, varscan2
- SLTM | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV99989429; called by muse, mutect2
- SMG8 | c.674G>C p.R225P | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV99959144; called by muse, mutect2, varscan2
- SMYD1 | c.915G>C p.M305I | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101352541; called by muse, mutect2
- SNX8 | c.1088A>G p.N363S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99771209; called by muse, mutect2, varscan2
- SOX3 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100983771; called by muse, mutect2, varscan2
- SPACA4 | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV99614514; called by muse, mutect2, varscan2
- SPATA1 | c.468C>A p.F156L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99760000; called by muse, mutect2, varscan2
- SPATA31D1 | c.1076G>T p.W359L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV100783101; called by muse, mutect2, varscan2
- SPNS3 | c.1323G>T p.Q441H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100337158; called by mutect2, varscan2
- SPOP | c.79-1G>C p.X27_splice | Splice Site (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100753651, COSV61654907; called by muse, mutect2, varscan2
- SPRR1B | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as rs781282352, COSV100198426; called by muse, mutect2
- SPTB | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs759151834, COSV101072454; called by muse, mutect2
- SSX5 | c.337C>T p.P113S (on ENST00000347757 / NM_175723.1; = p.P154S on NM_021015.4) | Missense Mutation (SNP) | VAF 63/330 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.18); catalogued as COSV100308912; called by muse, mutect2, varscan2
- STAB2 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs758420330, COSV66339017; called by muse, mutect2, varscan2
- STAG3 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV99445159; called by muse, mutect2
- STK10 | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs772430304, COSV51577187, COSV51577795; called by muse, mutect2, varscan2
- SUPT20H | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100634837; called by muse, mutect2, varscan2
- SVEP1 | c.4301G>C p.G1434A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100239277; called by muse, mutect2
- SYT9 | c.1105C>A p.L369M | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.739); catalogued as COSV100607768; called by muse, mutect2, varscan2
- TAB3 | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV99916903; called by muse, mutect2, varscan2
- TAOK1 | c.1289C>G p.S430* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99914882; called by mutect2, varscan2
- TARS3 | c.1672T>A p.C558S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV100255085; called by muse, mutect2, varscan2
- TBX5 | c.162C>G p.I54M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV100092359; called by muse, mutect2, varscan2
- TCEAL2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100216423; called by muse, varscan2
- TCHHL1 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 32/307 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as COSV100916631; called by muse, varscan2
- TCIRG1 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99693311; called by mutect2, varscan2
- TECPR1 | c.3020G>C p.G1007A | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV101130808, COSV65783644; called by muse, mutect2
- TENM1 | c.1097G>T p.R366M | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.055); catalogued as COSV100949771; called by muse, mutect2, varscan2
- TET2 | c.1687G>T p.G563* | Nonsense Mutation (SNP) | VAF 23/104 reads (22%) | catalogued as COSV99485208; called by muse, mutect2, varscan2
- TFDP3 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs1342946300, COSV100033586; called by muse, mutect2, varscan2
- TGFB1I1 | c.727C>G p.L243V (on ENST00000394863 / NM_001042454.3; = p.L226V on NM_015927.4) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100691259; called by muse, mutect2, varscan2
- TGFBR2 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs1263124193, COSV99848332; called by mutect2, varscan2
- THRAP3 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); catalogued as COSV100663671; called by muse, mutect2
- TKTL1 | c.478C>G p.H160D | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV99474235; called by muse, mutect2
- TLE4 | c.298C>G p.P100A | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99513411; called by muse, mutect2
- TLN1 | c.4834G>C p.G1612R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.181); catalogued as COSV100148325; called by muse, mutect2, varscan2
- TLN1 | c.2561G>T p.R854L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV100148327, COSV59210962; called by muse, mutect2, varscan2
- TLR8 | c.569C>A p.T190N (on ENST00000218032 / NM_138636.5; = p.T208N on NM_016610.4) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99487372; called by muse, mutect2, varscan2
- TMEM132D | c.2743G>C p.D915H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101243122, COSV67160573; called by muse, mutect2, varscan2
- TMEM170A | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as COSV100713293; called by muse, mutect2, varscan2
- TNFRSF9 | c.100+1G>A p.X34_splice | Splice Site (SNP) | VAF 22/72 reads (31%) | catalogued as rs754024907, COSV101097393; called by muse, mutect2
- TOX2 | c.320G>T p.G107V (on ENST00000358131 / NM_001098798.2; = p.G56V on NM_032883.3) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV100364810; called by muse, mutect2, varscan2
- TPP2 | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101060496; called by muse, mutect2, varscan2
- TRHDE | c.2129A>T p.E710V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.294); catalogued as rs1313567515, COSV53853897; called by mutect2, varscan2
- TRIM22 | c.40A>T p.T14S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.338); catalogued as COSV101181558; called by muse, mutect2, varscan2
- TRIM42 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV99648925; called by muse, mutect2
- TRIM6-TRIM34 | c.1812G>C p.Q604H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100709244; called by muse, mutect2, varscan2
- TRIML2 | c.713G>C p.R238T | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100456402; called by muse, mutect2
- TRUB1 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100076248; called by muse, mutect2
- TTC27 | c.13del p.E5Sfs*5 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as COSV58656109; called by mutect2, pindel, varscan2
- TTC37 | c.3065C>T p.A1022V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV100706946; called by muse, mutect2, varscan2
- TUBGCP3 | c.922A>G p.T308A | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99997356; called by muse, mutect2, varscan2
- TYR | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54477366, COSV99635530; called by muse, mutect2, varscan2
- USP33 | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); catalogued as COSV100657267; called by muse, mutect2
- VASH2 | c.754G>T p.V252F (on ENST00000517399 / NM_001301056.2; = p.V208F on NM_024749.5) | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55118677, COSV99663745; called by muse, mutect2, varscan2
- VPS16 | c.976T>G p.F326V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as COSV100988660; called by muse, mutect2, varscan2
- VWC2L | c.416G>C p.C139S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100436450; called by muse, mutect2, varscan2
- WDFY3 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99886052; called by muse, mutect2, varscan2
- WDR12 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99651279; called by mutect2, varscan2
- WIPF1 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99769173, COSV99769581; called by muse, mutect2, varscan2
- WNK1 | c.4616G>C p.G1539A (on ENST00000315939 / NM_018979.4; = p.G1292A on NM_014823.3) | Missense Mutation (SNP) | VAF 98/500 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); catalogued as COSV100268853; called by muse, mutect2, varscan2
- WWC3 | c.1816G>T p.V606L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as rs772417452, COSV101081927; called by muse, mutect2, varscan2
- XAGE5 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100657864, COSV63567544; called by muse, mutect2, varscan2
- YLPM1 | c.1933C>A p.Q645K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.046); catalogued as COSV99460697, COSV99461600; called by muse, varscan2
- YLPM1 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.045); catalogued as rs765280309, COSV99461604; called by muse, varscan2
- YY2 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 194/427 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100810865; called by muse, mutect2, varscan2
- ZBTB21 | c.285G>C p.E95D | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.255); catalogued as COSV100177392; called by muse, mutect2, varscan2
- ZBTB21 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.849); catalogued as COSV100177394; called by muse, mutect2, varscan2
- ZBTB41 | c.2408C>G p.S803C | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV100963501; called by muse, mutect2
- ZFHX4 | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51481987, COSV99268629; called by muse, mutect2, varscan2
- ZFHX4 | c.6539C>G p.T2180R | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51454526, COSV99268633; called by muse, mutect2, varscan2
- ZFP42 | c.558C>A p.S186R | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.103); catalogued as COSV100479209, COSV58819423; called by muse, mutect2, varscan2
- ZHX3 | c.1094C>G p.P365R | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100476873; called by muse, mutect2, varscan2
- ZMYND8 | c.2723C>T p.S908L (on ENST00000311275 / NM_001363741.2; = p.S882L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53682245, COSV53693783; called by muse, mutect2, varscan2
- ZNF213 | c.252C>G p.I84M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1203431802, COSV101206060; called by muse, mutect2, varscan2
- ZNF233 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100492502; called by muse, mutect2, varscan2
- ZNF264 | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54041073; called by muse, mutect2, varscan2
- ZNF285 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV100450224; called by muse, mutect2, varscan2
- ZNF296 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99674203; called by muse, mutect2
- ZNF311 | c.8A>C p.E3A | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV101014299; called by muse, mutect2, varscan2
- ZNF347 | c.2194A>C p.T732P | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100498476; called by muse, mutect2, varscan2
- ZNF394 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV61794406; called by muse, mutect2
- ZNF443 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV100042426; called by muse, mutect2, varscan2
- ZNF445 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201335323, COSV68538911; called by mutect2, varscan2
- ZNF451 | c.2563G>C p.D855H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.293); catalogued as COSV100675156; called by muse, mutect2, varscan2
- ZNF479 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV100483090, COSV100483149; called by muse, mutect2, varscan2
- ZNF563 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV99536829; called by muse, mutect2
- ZNF585A | c.855G>T p.L285F (on ENST00000292841 / NM_001288800.2; = p.L230F on NM_152655.3) | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.516); catalogued as COSV99493679; called by muse, mutect2, varscan2
- ZNF804B | c.2786T>C p.L929S | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768332777, COSV100306679; called by muse, mutect2, varscan2
- ZNF804B | c.3376G>C p.D1126H | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100306680; called by muse, mutect2
- ZNF827 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV101061858; called by muse, mutect2, varscan2
- ZNF835 | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV101606388, COSV73379511; called by muse, mutect2, varscan2
- ZNF99 | c.410G>C p.W137S | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as COSV101233994, COSV68056227; called by muse, mutect2
- ASXL1 | c.3473del p.N1158Tfs*13 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- FNIP1 | c.652del p.A218Hfs*10 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- GPR179 | c.4802G>C p.R1601T (on ENST00000621958; = p.R1600T on NM_001004334.4) | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.02); called by muse, mutect2
- HNF1B | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- IGKV1D-43 | c.229del p.Q77Kfs*? | Frame Shift Del (DEL) | VAF 42/252 reads (17%) | called by pindel, varscan2
- IRS4 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.231); called by muse, mutect2
- KCNS3 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.64); called by muse, mutect2
- KIR3DL1 | c.734G>C p.S245T | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- LILRA6 | c.81del p.K28Nfs*11 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.774C>G p.S258R | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MYO19 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLGN1 | c.2446del p.H816Ifs*19 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- SLC35D1 | c.729+1del p.X243_splice | Splice Site (DEL) | VAF 41/229 reads (18%) | called by mutect2, pindel, varscan2
- SPATA31D1 | c.162del p.E55Kfs*45 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- SPP2 | c.409T>A p.S137T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.346); called by muse, mutect2
- SSU72P8 | c.121C>G p.H41D | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.085); called by muse, mutect2
- TBC1D4 | c.1210dup p.E404Gfs*8 | Frame Shift Ins (INS) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- TRDV1 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 29/215 reads (13%) | called by muse, mutect2, varscan2
- USP26 | c.138del p.K46Nfs*7 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- ZNF84 | c.1681C>G p.H561D | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ABCB11 | c.2910C>A p.P970= | Silent (SNP) | VAF 31/159 reads (19%) | catalogued as COSV99793332; called by muse, mutect2, varscan2
- ABCD4 | c.726G>T p.G242= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV100084615; called by muse, mutect2, varscan2
- ABHD17C | c.600G>T p.V200= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV99358847; called by muse, mutect2, varscan2
- AC006059.2 | c.645G>A p.P215= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs765190012, COSV59610233; called by muse, mutect2, varscan2
- AC008676.3 | c.354C>T p.A118= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100400532; called by muse, mutect2, varscan2
- AKAP14 | c.558C>T p.F186= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV57631310; called by muse, mutect2, varscan2
- AMOT | c.2214T>C p.N738= (on ENST00000371959 / NM_001113490.1; = p.N329= on NM_133265.3) | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100495633; called by muse, mutect2
- ANKLE2 | c.843G>A p.L281= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100514399; called by muse, mutect2, varscan2
- ARHGAP29 | c.2082G>A p.E694= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs1366119165, COSV53112933, COSV99559174; called by muse, mutect2, varscan2
- ARHGAP39 | c.843C>T p.L281= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99432407; called by muse, mutect2, varscan2
- ARHGEF2 | c.1768C>T p.L590= (on ENST00000361247 / NM_001162383.2; = p.L562= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as COSV100561280; called by muse, mutect2, varscan2
- ATP6V0A2 | c.852G>A p.L284= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as COSV100377207; called by muse, mutect2
- AXDND1 | c.1299C>T p.Y433= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100858730; called by muse, mutect2, varscan2
- BAZ2B | c.1152G>C p.V384= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV100601088; called by muse, mutect2, varscan2
- BCL10 | c.516G>A p.L172= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100997850; called by muse, mutect2, varscan2
- BCOR | c.1848C>A p.G616= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV100654313; called by muse, mutect2, varscan2
- BICD1 | c.75G>C p.T25= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99863108; called by muse, mutect2, varscan2
- BRINP1 | c.822G>C p.P274= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV99777141; called by muse, mutect2, varscan2
- C1S | c.1416G>T p.T472= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100196806; called by muse, mutect2, varscan2
- C3 | c.3135C>A p.A1045= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99837380; called by muse, mutect2, varscan2
- CCDC170 | c.2091A>G p.K697= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99498971; called by muse, mutect2, varscan2
- CCNB3 | c.3711G>A p.Q1237= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV99330009; called by muse, mutect2, varscan2
- CLDN3 | c.129G>A p.Q43= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV101230862; called by muse, mutect2
- CLEC17A | c.834C>T p.A278= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100355610; called by muse, mutect2, varscan2
- CNTN3 | c.2067C>T p.P689= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV99726302; called by muse, mutect2, varscan2
- COL21A1 | c.273C>T p.L91= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs182718262, COSV55156646, COSV99780013; called by mutect2, varscan2
- COL22A1 | c.2376C>T p.G792= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100281122; called by muse, mutect2, varscan2
- COPB2 | c.1185A>G p.A395= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as rs1460409766, COSV60813934; called by muse, mutect2
- CPM | c.339G>C p.L113= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV100615305; called by muse, mutect2, varscan2
- CPNE5 | c.228C>T p.F76= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs574969645, COSV55195626; called by muse, mutect2, varscan2
- CPVL | c.651C>T p.I217= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99606524; called by muse, mutect2, varscan2
- CREBZF | c.105G>C p.L35= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV99476502; called by muse, mutect2
- CSMD3 | c.4509C>A p.I1503= (on ENST00000297405 / NM_001363185.1; = p.I1399= on NM_052900.3) | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV99842965, COSV99850201; called by muse, mutect2
- DCTN2 | c.195G>A p.K65= (on ENST00000548249 / NM_001261413.2; = p.K70= on NM_006400.4) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV101461160; called by muse, mutect2, varscan2
- DDR1 | c.1611C>T p.P537= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as COSV100242227; called by muse, mutect2, varscan2
- DDX54 | c.684G>T p.V228= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV100014242; called by muse, mutect2, varscan2
- DLG3 | c.2106T>C p.Y702= (on ENST00000374360 / NM_021120.4; = p.Y397= on NM_020730.3) | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV99530180; called by muse, mutect2, varscan2
- DNAH11 | c.7863C>T p.V2621= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs755501742, COSV60972826, COSV60985085; called by muse, mutect2, varscan2
- DSCAM | c.1050T>C p.N350= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as COSV101261694; called by muse, mutect2, varscan2
- DST | c.5433C>T p.S1811= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99760659; called by mutect2, varscan2
- DZIP1L | c.1152C>G p.L384= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV100551782, COSV59523634; called by muse, mutect2
- EZH1 | c.1152A>G p.K384= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs1236362218, COSV101331462; called by muse, mutect2, varscan2
- FBN2 | c.4902C>G p.P1634= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs201071253, COSV99331195; called by muse, mutect2, varscan2
- FBN2 | c.2746C>T p.L916= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99331200; called by muse, mutect2
- FCGBP | c.10185C>T p.F3395= | Silent (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- FGD4 | c.2133G>T p.L711= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as COSV99847708; called by muse, mutect2, varscan2
- FMN2 | c.4353C>G p.V1451= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as COSV100147553; called by muse, mutect2
- FRMPD1 | c.1767G>T p.A589= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100899663, COSV66701239; called by muse, mutect2, varscan2
- GABRA6 | c.945C>T p.F315= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV99195298; called by muse, mutect2
- GGT7 | c.1428G>T p.V476= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV100322265; called by muse, mutect2, varscan2
- GJC2 | c.882G>C p.A294= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100813021; called by muse, mutect2, varscan2
- GLUD2 | c.1659T>C p.A553= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV100047151; called by muse, mutect2, varscan2
- GTPBP10 | c.63C>G p.L21= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV99746303; called by muse, mutect2
- H3C8 | c.276C>A p.A92= | Silent (SNP) | VAF 32/164 reads (20%) | catalogued as COSV100010389, COSV59952696; called by muse, mutect2, varscan2
- HDAC6 | c.900C>A p.G300= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100490535, COSV100491331; called by muse, mutect2, varscan2
- HIP1 | c.1320C>T p.L440= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV100418241; called by muse, mutect2, varscan2
- HMCN1 | c.390G>A p.L130= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99637027; called by muse, mutect2, varscan2
- HPGDS | c.357G>A p.L119= | Silent (SNP) | VAF 49/225 reads (22%) | catalogued as COSV99756152; called by muse, mutect2, varscan2
- HYDIN | c.4455G>C p.L1485= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV101143745, COSV66833147; called by muse, mutect2, varscan2
- IGHM | c.903C>T p.F301= | Silent (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- IGKV1D-8 | c.195C>A p.A65= | Silent (SNP) | VAF 34/207 reads (16%) | called by muse, mutect2, varscan2
- IRS4 | c.1653C>A p.G551= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as COSV100929800; called by muse, mutect2
- ITIH6 | c.1353C>A p.R451= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV54486435, COSV99514118; called by muse, mutect2, varscan2
- KASH5 | c.1080G>A p.L360= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV101483520; called by mutect2, varscan2
- KBTBD2 | c.1860A>G p.L620= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100406615; called by muse, mutect2, varscan2
- KCND1 | c.432C>A p.A144= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV54415189, COSV99502184; called by muse, mutect2, varscan2
- KCNV1 | c.639C>A p.G213= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs374133519, COSV99819497; called by muse, mutect2, varscan2
- KIR3DL3 | c.720G>A p.V240= | Silent (SNP) | VAF 26/337 reads (8%) | called by muse, mutect2
- KPNA4 | c.735A>T p.P245= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100515385; called by muse, mutect2, varscan2
- L3HYPDH | c.564C>T p.G188= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs753745830, COSV99904410; called by muse, mutect2, varscan2
- LAMC3 | c.3051C>T p.Y1017= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs537864425, COSV63088255; called by mutect2, varscan2
- LCE4A | c.54C>A p.I18= | Silent (SNP) | VAF 25/190 reads (13%) | catalogued as COSV100140116; called by muse, mutect2, varscan2
- LRP2 | c.13698C>T p.N4566= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV99790581; called by muse, mutect2, varscan2
- LRRTM3 | c.621C>G p.L207= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV100791952; called by muse, mutect2
- MAGEB6B | c.552T>A p.A184= | Silent (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- MAP1B | c.375C>A p.R125= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV99703018; called by muse, mutect2, varscan2
- MAP9 | c.579A>T p.G193= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV100251154; called by muse, mutect2, varscan2
- MC2R | c.717C>A p.V239= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100563243; called by muse, mutect2, varscan2
- MCMBP | c.168C>A p.P56= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100750192; called by muse, mutect2, varscan2
- MEFV | c.618C>T p.N206= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV54825554; called by muse, mutect2, varscan2
- MEOX2 | c.780G>A p.V260= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as COSV100012600; called by muse, mutect2
- MGAT4C | c.1389A>C p.T463= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100153482; called by muse, mutect2, varscan2
- MNDA | c.207C>A p.A69= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV100933461; called by muse, mutect2, varscan2
- MUC16 | c.33133C>T p.L11045= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs889386890, COSV101201997, COSV67490431; called by muse, mutect2, varscan2
- MYEOV | c.444G>T p.G148= | Silent (SNP) | VAF 18/380 reads (5%) | catalogued as COSV100456758; called by muse, mutect2
- MYH1 | c.2964T>C p.G988= | Silent (SNP) | VAF 32/192 reads (17%) | catalogued as COSV99877080; called by muse, mutect2, varscan2
- MYRIP | c.1390C>A p.R464= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV56875183, COSV56881253; called by muse, mutect2, varscan2
- NAV3 | c.4881T>A p.L1627= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV99896450; called by muse, varscan2
- NCAN | c.3558G>A p.V1186= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV99388499; called by muse, mutect2, varscan2
- NIPBL | c.57C>T p.L19= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV56949014; called by muse, mutect2, varscan2
- NKX2-1 | c.183C>T p.H61= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV100702058; called by muse, mutect2, varscan2
- NR3C2 | c.963G>T p.T321= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs529946671, COSV100679896; called by muse, mutect2, varscan2
- OR10J1 | c.816G>C p.L272= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV101419897, COSV101419991; called by muse, mutect2, varscan2
- OR10Q1 | c.183C>G p.T61= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100372423; called by muse, mutect2, varscan2
- OR14K1 | c.444C>T p.L148= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV99315541; called by muse, mutect2
- OR2T33 | c.108C>A p.S36= | Silent (SNP) | VAF 29/162 reads (18%) | catalogued as COSV100532339, COSV58817365; called by muse, mutect2, varscan2
- OR4C11 | c.480G>T p.L160= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV100155560; called by muse, mutect2, varscan2
- OR4C3 | c.334C>T p.L112= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV100168385; called by muse, mutect2, varscan2
- OR56B4 | c.210C>A p.G70= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100337709; called by muse, mutect2, varscan2
- OR6B1 | c.345G>C p.L115= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV101281676; called by muse, mutect2, varscan2
- OR9Q1 | c.846C>A p.P282= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV59048912; called by muse, mutect2, varscan2
- P3H3 | c.564G>C p.L188= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV99301774; called by muse, mutect2
- PALM2AKAP2 | c.714A>G p.A238= (on ENST00000259318 / NM_001136562.3; = p.A469= on NM_007203.5) | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV52180603, COSV99395854; called by muse, mutect2, varscan2
- PCDHA7 | c.1620G>C p.A540= | Silent (SNP) | VAF 39/208 reads (19%) | catalogued as rs1456412206, COSV100971915, COSV65343603; called by muse, mutect2, varscan2
- PCDHB7 | c.1806G>T p.L602= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as COSV99177510; called by muse, mutect2, varscan2
- PCDHGA6 | c.1500C>A p.P500= | Silent (SNP) | VAF 29/190 reads (15%) | catalogued as COSV99548599; called by muse, mutect2, varscan2
- PCDHGA7 | c.1779G>C p.A593= | Silent (SNP) | VAF 25/133 reads (19%) | catalogued as COSV99529047, COSV99548601; called by muse, mutect2, varscan2
- PDIA5 | c.654C>T p.I218= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV100299789; called by muse, mutect2, varscan2
- PECR | c.909C>G p.L303= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV99527014; called by muse, mutect2, varscan2
- PIK3CG | c.1401G>T p.L467= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs752517413, COSV100782629; called by muse, mutect2, varscan2
- PKD1 | c.5661C>T p.I1887= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs372696163; called by mutect2, varscan2
- PLEK | c.408T>A p.T136= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV99311283; called by muse, mutect2, varscan2
- PLXNC1 | c.4269G>A p.L1423= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99314016; called by muse, mutect2, varscan2
- POLR3A | c.408C>T p.Y136= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV100965821; called by muse, mutect2, varscan2
- POU3F4 | c.69G>A p.A23= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1243005603, COSV100937266, COSV100937355; called by muse, mutect2, varscan2
- PPP1R3F | c.1515G>C p.A505= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99278275, COSV99278903, COSV99279059; called by muse, mutect2, varscan2
- PRKD1 | c.2241C>T p.P747= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs147092748; called by muse, mutect2, varscan2
- PRKDC | c.10977C>T p.F3659= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100043307; called by muse, mutect2, varscan2
- PROX1 | c.1368C>A p.A456= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as COSV99800341, COSV99800457; called by muse, mutect2, varscan2
- PTPRC | c.1179A>G p.G393= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV100723287, COSV61420348; called by muse, mutect2, varscan2
- RIN3 | c.1092C>A p.A364= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs760819627, COSV53653134; called by muse, mutect2
- RIPK4 | c.1689G>A p.G563= (on ENST00000352483; = p.G515= on NM_020639.3) | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs1273767052, COSV100205441; called by muse, mutect2, varscan2
- RPRML | c.210C>A p.I70= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV100462020, COSV59262887; called by muse, mutect2, varscan2
- RS1 | c.597C>A p.I199= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as rs200052722, COSV101183862; ClinVar: likely benign; called by muse, mutect2, varscan2
- RUNX1T1 | c.543C>A p.V181= (on ENST00000265814 / NM_001198628.1; = p.V154= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV56155006; called by muse, mutect2, varscan2
- RYR2 | c.5478T>C p.Y1826= | Silent (SNP) | VAF 54/247 reads (22%) | catalogued as rs1264479029, COSV100773188, COSV63721064; called by muse, mutect2, varscan2
- SATL1 | c.942G>A p.L314= (on ENST00000395409; = p.L501= on NM_001012980.2) | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV100261132; called by mutect2, varscan2
- SCUBE2 | c.630G>A p.Q210= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV100497020; called by muse, mutect2, varscan2
- SEMA3C | c.1437C>G p.V479= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV99544087; called by muse, mutect2
- SFRP4 | c.315C>A p.R105= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV52259009, COSV99554729; called by muse, mutect2, varscan2
- SH3RF3 | c.894G>T p.A298= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100513977; called by muse, mutect2, varscan2
- SIM1 | c.1119C>T p.S373= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV53494543, COSV53497893; called by muse, mutect2, varscan2
- SLC19A1 | c.1263G>T p.V421= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV100229697, COSV60753462; called by muse, mutect2, varscan2
- SLC26A4 | c.1677C>T p.V559= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs774173683, COSV55915864; called by muse, mutect2, varscan2
- SLC32A1 | c.1050C>A p.L350= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV54146545, COSV99462712, COSV99462742; called by muse, mutect2, varscan2
- SLC4A10 | c.486T>C p.L162= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99766209; called by muse, mutect2, varscan2
- SLC8A2 | c.585G>A p.L195= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV52639324; called by muse, mutect2, varscan2
- SNX32 | c.408G>A p.A136= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs778115486, COSV57448834; called by mutect2, varscan2
- SOHLH2 | c.1158A>C p.S386= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV101157999; called by muse, mutect2, varscan2
- SPATA18 | c.589C>A p.R197= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99731396; called by muse, mutect2, varscan2
- STXBP5L | c.1971G>T p.G657= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV99876735; called by muse, mutect2, varscan2
- SYNE1 | c.1791C>G p.L597= (on ENST00000367255 / NM_182961.4; = p.L604= on NM_033071.3) | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99582460; called by muse, mutect2, varscan2
- SYNE1 | c.666G>T p.P222= (on ENST00000367255 / NM_182961.4; = p.P229= on NM_033071.3) | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV55036659, COSV99582469; called by muse, mutect2, varscan2
- SYNJ2 | c.4086T>C p.N1362= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100840685; called by muse, mutect2, varscan2
- TAS2R38 | c.264G>A p.L88= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as COSV71885326; called by muse, mutect2
- TENM4 | c.4386C>A p.A1462= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99580303; called by muse, mutect2, varscan2
- TEX15 | c.3825G>C p.V1275= (on ENST00000256246; = p.V1658= on NM_001350162.2) | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99822293; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1284C>T p.L428= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV99305616; called by muse, mutect2, varscan2
- TMEM39A | c.870C>T p.F290= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100052668; called by muse, mutect2, varscan2
- TNXB | c.5997T>G p.P1999= (on ENST00000647633; = p.P1752= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100926734; called by muse, varscan2
- TPRX1 | c.819C>G p.A273= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100445945; called by mutect2, varscan2
- TRHR | c.276C>A p.V92= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as COSV100305145; called by muse, mutect2, varscan2
- UBE2S | c.225C>T p.P75= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99198792; called by muse, mutect2, varscan2
- UBIAD1 | c.456G>C p.L152= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs555247860, COSV100954953; called by muse, mutect2, varscan2
- UNC5C | c.267C>A p.T89= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV101498060; called by muse, mutect2, varscan2
- VGLL3 | c.645G>T p.V215= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV101052088; called by muse, mutect2, varscan2
- WAS | c.141C>A p.A47= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100939542; called by muse, mutect2, varscan2
- ZC3H13 | c.3942G>A p.E1314= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV99669042; called by muse, mutect2, varscan2
- ZEB2 | c.3264G>A p.R1088= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs774763773, COSV100357090; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZIC4 | c.405C>G p.A135= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV101268189, COSV67172205; called by muse, mutect2, varscan2
- ZNF208 | c.2160C>G p.P720= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as COSV101237250; called by muse, varscan2
- ZNF234 | c.1638G>A p.G546= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV101468428; called by muse, mutect2, varscan2
- ZNF43 | c.999G>A p.K333= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100731987; called by mutect2, varscan2
- ZNF473 | c.1615A>C p.R539= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV99569187; called by muse, mutect2, varscan2
- ZNF536 | c.1998G>T p.V666= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100836104; called by muse, mutect2, varscan2
- ZNF597 | c.384A>T p.P128= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV100072189; called by muse, mutect2, varscan2
- ZNF683 | c.1011C>G p.L337= | Silent (SNP) | VAF 37/179 reads (21%) | catalogued as rs1444540350, COSV100853755, COSV62875855; called by muse, mutect2, varscan2
- ZNF808 | c.1857A>G p.G619= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs1261001971, COSV100708254; called by muse, mutect2, varscan2
- BX119917.1 | n.88G>A | RNA (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- CCNQP1 | n.126C>A | RNA (SNP) | VAF 56/217 reads (26%) | called by muse, mutect2, varscan2
- DST | c.4297-4836C>T | Intron (SNP) | VAF 11/127 reads (9%) | catalogued as COSV99760661; called by muse, mutect2
- DUOXA1 | chr15:45117572 G>C | 3'Flank (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99973621; called by muse, mutect2, varscan2
- FAM160A2 | c.1435+28G>A | Intron (SNP) | VAF 42/140 reads (30%) | catalogued as COSV99792598; called by muse, mutect2, varscan2
- HBD | chr11:5232797 A>C | 3'Flank (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99496717, COSV99496910; called by muse, mutect2, varscan2
- LEKR1 | c.*525G>T | 3'UTR (SNP) | VAF 24/122 reads (20%) | catalogued as COSV100739393; called by muse, mutect2, varscan2
- METTL17 | c.1265+27G>C | Intron (SNP) | VAF 20/146 reads (14%) | catalogued as COSV100068748; called by muse, mutect2, varscan2
- MIR513C | n.24G>A | RNA (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- MIR890 | n.73T>A | RNA (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2, varscan2
- OR3A4P | n.624G>T | RNA (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- PAX8 | c.-1G>A | 5'UTR (SNP) | VAF 8/50 reads (16%) | catalogued as rs774204378, COSV54511330; called by mutect2, varscan2
- PHYHD1 | c.*35G>T | 3'UTR (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100455303; called by muse, mutect2, varscan2
- PTGER3 | c.*24-12872C>A | Intron (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.10360+3772A>G | Intron (SNP) | VAF 18/131 reads (14%) | catalogued as rs779606984, COSV100633702; called by muse, mutect2, varscan2
- VPS28 | c.549-58del | Intron (DEL) | VAF 17/94 reads (18%) | called by mutect2, pindel, varscan2
- WASF3 | c.717-934G>T | Intron (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100099688; called by muse, mutect2, varscan2
- WASF4P | n.919G>A | RNA (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
